Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-5886, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-5886-01A (Primary Tumor).

[page 1 of 3]
Patient Name: [REDACTED]

Med. Rec. #: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

Ref. Physician: [REDACTED]

Patient Address: [REDACTED]

Ref. Source: [REDACTED]

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to: [REDACTED]

Clinical Diagnosis & History:

[REDACTED] h 1.5 cm left lower pole renal mass.

Specimens Submitted:

1: Kidney, left lower pole, partial nephrectomy [REDACTED]

2: Kidney, left lower pole cyst, excision [REDACTED]

DIAGNOSIS:

1. Kidney, left lower pole, partial nephrectomy [REDACTED]

Tumor Type:

Renal cell carcinoma - Papillary type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 1.5 cm.

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

The tumor is focally present approximately 1 mm from the inked soft tissue margin surrounding the kidney. The closest kidney resection margin is 0.5 cm.

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3a Tumor invades the adrenal gland or perinephric tissues but not beyond Gerota's fascia

Note: Immunohistochemical stains were performed and the tumor is positive for CK7 and racemase, it is negative for CK20 while it shows granular, non-specific staining for c-kit, 34BE12 and 4A4. This immunoprofile is consistent with the diagnosis of papillary renal cell carcinoma.

2. Kidney cyst, left lower pole, excision:

[page 2 of 3]
- Benign renal cyst.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	CK7	
	CK20	
	TTF-1	
	RACEMASE	
	IMM RECUT	
	NEG CONT	
	4A4/P63	
	34BE12	
	CD117	
	RECUT	
	IMM RECUT	
	NEG CONT	

Gross Description:

1). The specimen is received fresh for frozen section consultation and is labeled "Left renal tumor, lower pole". It consists of a 3.5 x 2.5 x 2 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black, the remaining surface is inked green and the specimen is serially sectioned to reveal a brown tan, fairly circumscribed focally hemorrhagic tumor, measuring 1.5 x 1.2 x 1cm. The clearance from the resection margin is 0.5 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Entirely submitted. Portions of the tumor are submitted for TPS.

Summary of sections:

FSC - frozen section control

T - tumor

M - margin

RS - remaining sections

2). The specimen is received in formalin, labeled "Left lower pole kidney cyst" and consists of a two fragment of tan soft tissue, measuring 1.6 and 3.2cm in greatest dimension.. Entirely submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: Kidney, left lower pole, partial nephrectomy

Block	Sect. Site	PCs
1	FSC	1
1	M	1
2	RS	4
1	T	1

Part 2: Kidney, left lower pole cyst, excision

Block	Sect. Site	PCs
1	U	2

[page 3 of 3]
Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation

1. FROZEN SECTION DIAGNOSIS: SP: LEFT RENAL TUMOR, LOWER POL [REDACTED] DEEP INKED MARGIN
NEGATIVE; RENAL CORTICAL NEOPLASM SUSPECT PAPILLARY TYPE (FELDSTEIN).
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file c70f117c-4b16-4f25-beba-e098a3cb467d (TCGA-BQ-5886.955905DE-48F3-4AC4-94A7-B8CC91F34117.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).